Gene-level copy-number profile of tumor specimen TCGA-13-0920-01A from TCGA case TCGA-13-0920, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.9 years (24,064 days).
Specimen TCGA-13-0920-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a2f4000b-1021-4696-8f3c-ed7de514cb2f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0920-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/a3bc85bf-90e6-4907-a9db-b59085b01ea6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3,676; copy number 2: 8,711; copy number 3: 17,313; copy number 4: 12,889; copy number 5: 10,206; copy number 6: 4,792; copy number 7: 1,707; copy number 8: 303; copy number 9: 176; copy number 10: 36.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,522,666–181,523,001, 1 gene: AC093840.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,222 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:44,721,786–58,546,734, 341 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr1:162,979,551–164,980,137, 25 genes, copy number 7: AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P.
- chr1:237,042,184–240,776,824, 50 genes, copy number 8 (within-gene range 6–8): RYR2, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8.
- chr1:240,823,006–240,823,433, 1 gene, copy number 8: RFKP1.
- chr1:246,509,038–247,008,093, 19 genes, copy number 8 (within-gene range 6–8): AL356583.1, LINC01743, AL356583.3, AL356583.2, TFB2M, CNST, AL591623.1, AL591623.2, AL591848.2, AL591848.1, SCCPDH, RPL35AP6, KIF28P, AL591848.3, LINC01341, AC113174.1, AC113174.2, AHCTF1, ZNF695.
- chr2:11,658,178–14,992,066, 29 genes, copy number 7: NTSR2, CDK8P1, AC106875.2, LPIN1, AC106875.1, AC012456.1, AC012456.2, MIR548S, MIR3681HG, MIR4262, SNORD18, MIR3681, RNU6-843P, AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1, AC093912.1, AC073062.1, LINC00276, AC016730.1, RNU6-1288P, Metazoa_SRP, AC011897.1, LRATD1, AC068286.2, AC068286.1.
- chr2:66,235,377–67,684,077, 21 genes, copy number 7: AC118345.1, AC092669.1, MIR4778, LINC01873, MEIS1-AS3, MEIS1, MEIS1-AS2, LINC01798, LINC01797, DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1, AC010987.1.
- chr2:115,835,129–120,179,119, 42 genes, copy number 7–9 (within-gene range 6–9): AC016721.1, AC104408.1, AC062016.1, MTCYBP39, AC062016.2, MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1, AC064856.1, AC009312.1, DDX18, AC009404.1, HTR5BP, CCDC93, AC009303.1, AC009303.2, AC009303.3, AC009303.4, RN7SL111P, INSIG2, THORLNC, LINC01956, EN1, MARCO, AC013457.1, C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5.
- chr2:134,455,759–137,677,718, 33 genes, copy number 7 (within-gene range 6–7): TMEM163, AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19, RAB3GAP1, SNORA40B, ZRANB3, G3BP1P1, R3HDM1, RNU6-512P, MIR128-1, UBXN4, LCT, Y_RNA, LCT-AS1, MCM6, MANEALP1, DARS1, DARS-AS1, AC068492.1, CXCR4, HNRNPKP2, AC112255.1, UBBP1, RN7SKP141, SMC4P1, THSD7B, RNA5SP105.
- chr2:151,114,811–154,697,817, 44 genes, copy number 7 (within-gene range 6–7): AC018731.1, FABP5P10, RBM43, NMI, TNFAIP6, MIR4773-1, MIR4773-2, RN7SL124P, RIF1, NEB, ARL5A, AC097448.1, AC068547.1, CACNB4, AC079790.1, STAM2, RPL30P2, AC079790.2, Y_RNA, FMNL2, NUDCP1, AC012066.1, AC012443.1, AC012443.2, PRPF40A, ARL6IP6, AC009969.1, UBQLN4P2, ATP5PBP4, AC011901.1, AC079150.1, LINC01850, RPL23AP29, TUBAP13, AC012501.2, AC012501.1, RPRM, DNAJA1P2, GALNT13, PHBP4, AC009227.1, AC009227.2, RNA5SP107, AC061961.1.
- chr3:146,342,996–146,544,856, 5 genes, copy number 7: AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1.
- chr6:47,656,436–52,087,613, 53 genes, copy number 7: ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5, AL158050.2, AL158050.1, AL365219.1, AL445529.1, AL355997.1, PKHD1, RN7SL580P.
- chr6:53,196,720–69,389,506, 136 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr6:73,693,903–79,947,553, 73 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:41,653,220–41,896,762, 1 gene, copy number 7 (within-gene range 5–7): ANK1.
- chr8:41,803,349–47,198,861, 86 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:120,380,761–142,766,427, 307 genes, copy number 7–9 (broad region; genes not listed).
- chr10:36,626,015–37,384,111, 12 genes, copy number 7: Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P.
- chr10:53,458,197–59,960,913, 45 genes, copy number 7–8: RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC010996.1, AC025039.1, MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM, BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553.
- chr10:60,050,668–60,081,854, 2 genes, copy number 8: AL592430.1, Y_RNA.
- chr10:75,243,568–78,697,022, 54 genes, copy number 9: ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1, AC013738.1, ATP5MC1P8, KCNMA1, KCNMA1-AS1, KCNMA1-AS2, AL731575.1, KCNMA1-AS3, COX6CP15, RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1, AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71, AL583852.1, AC016820.1.
- chr10:84,328,586–84,561,263, 5 genes, copy number 7 (within-gene range 5–7): CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5.
- chr11:73,264,505–97,000,711, 497 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr11:112,602,354–112,835,124, 5 genes, copy number 8: AP003063.1, AP003100.2, AP003100.3, AP003100.1, AC016902.1.
- chr12:30,086,342–34,249,958, 105 genes, copy number 7–9 (broad region; genes not listed).
- chr12:42,615,221–44,389,762, 24 genes, copy number 7: LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1.
- chr12:69,901,918–70,243,379, 1 gene, copy number 10 (within-gene range 3–10): PRANCR.
- chr12:70,180,338–70,637,440, 9 genes, copy number 10: LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:70,671,918–70,672,856, 1 gene, copy number 10: FAHD2P1.
- chr20:87,250–6,220,759, 196 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,775. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
